Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4370, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4370-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Not specified. Tumor configuration: Not specified. Tumor size: 7 x 6 x 1 cm. Histologic type: Adenocarcinoma. Histologic grade: Moderately differentiated. Extent of invasion: Not specified. Lymph nodes: Not specified. Margins – Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 0b62f2d9-b5dd-4050-bbf5-ed72dcfa01c9 (TCGA-BR-4370.E22B59ED-FFA1-41CA-B067-EE94F7495074.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).